Surgical pathology report (de-identified scan), TCGA case TCGA-CW-6087, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-6087-01A (Primary Tumor).

TCGA-CW-6087

Surgical Pathology
REVISED REPORT (Addendum/Procedure included)

TISSUE DESCRIPTION:

Right kidney (515 grams, 16.5 x 7.5 x 5.4 cm) with 9 cm of attached ureter, left adrenal gland (36.42 grams, 7.5 x 4 x 3.2 cm), paracaval lymph node (1.5 x 1.5 x 1 cm), and inter aortic caval lymph node (2.5 x 1 x 1 cm).

DIAGNOSIS:

Kidney, right, radical nephrectomy: Grade 4 (of 4) renal cell carcinoma, clear cell type, forming a 8.2 x 6.2 x 5.3 cm mass located in the inferior pole. The tumor extends into the peripheral perinephric fat. The renal vein is grossly free of tumor. The tumor invades into the collecting system. Coagulative tumor necrosis is present. The surgical margins are negative. No renal hilar lymph nodes are identified.

Adrenal gland, left, adrenalectomy: Metastatic renal cell carcinoma forming a mass (7.3 x 3.8 x 3 cm) within the adrenal parenchyma.

Lymph node, paracaval, excision: A single paracaval lymph node is positive for metastatic renal cell carcinoma.

Lymph node, inter aortic caval, excision: A single inter aortic caval lymph node is negative for tumor.

ADDENDUM:

On permanent sections, sarcomatoid differentiation is identified.

Source: NCI Genomic Data Commons file 68ccea14-7911-4ef4-a33f-2adb3fb08f3d (TCGA-CW-6087.236A0265-E30C-4D52-839D-ABB624E2FEEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).